Somatic mutation profile of tumor specimen ER-ABDX-TTP1-A (aliquot ER-ABDX-TTP1-A-2-0-D-A46L-34) from EXCEPTIONAL_RESPONDERS case ER-ABDX, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.0 years (24,467 days).
Specimen ER-ABDX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 467dbc81-92e4-477c-880f-96bad777e21a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ABDX-NT1-A (Solid Tissue Normal), aliquot ER-ABDX-NT1-A-1-0-D-A46L-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5b27701-40c9-447c-9dd1-5f53c8cb5817

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Splice Site 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1592C>T p.T531M (on ENST00000399959; = p.T532M on NM_001356.5) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795387, COSV67863875; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/131 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL14A1 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV52852040; called by muse, mutect2, varscan2
- SI | c.3802G>A p.D1268N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100017141; called by muse, mutect2
- TP53 | c.704del p.N235Tfs*12 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as CM951230, COSV52700907, COSV52979785, COSV52987012; called by mutect2, pindel
- WNK4 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs387907556, COSV55905192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BHMT2 | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, varscan2
- HEATR3 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- IPO5 | c.1679G>A p.C560Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KANK1 | c.1413_1448del p.L472_R483del | In Frame Del (DEL) | VAF 5/64 reads (8%) | called by mutect2, pindel
- KIAA0319 | c.3040+1G>C p.X1014_splice | Splice Site (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- PGR | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2
- CHST8 | c.411G>T p.P137= | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- ICE1 | c.3576T>C p.S1192= | Silent (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- LILRA2 | c.576G>A p.S192= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as rs763571960, COSV52190338; called by muse, varscan2
- RGS22 | c.1917C>T p.Y639= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs200708091, COSV62658468; called by muse, mutect2, varscan2
- RHOT2 | c.72G>T p.L24= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- ZNF208 | c.2412C>A p.P804= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV101237266; called by muse, mutect2
- GNAS | c.257+1006C>T | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as rs950212353; called by muse, mutect2
- NAP1L6P | n.161G>A | RNA (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
